Somatic mutation profile of tumor specimen TCGA-A2-A4S3-01A (aliquot TCGA-A2-A4S3-01A-21D-A25Q-09) from TCGA case TCGA-A2-A4S3, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 59.6 years (21,762 days).
Specimen TCGA-A2-A4S3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9910d2b-381e-4e28-a3ae-805f17520aa9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A4S3-10A (Blood Derived Normal), aliquot TCGA-A2-A4S3-10A-01D-A25Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c659d46-99e8-423b-bc6d-9d386dbe9e60

The open-access MAF lists 68 somatic variants for this specimen: 45 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 21, Nonsense Mutation 3, Splice Site 2, RNA 1, Translation Start Site 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.394A>G p.K132E | Missense Mutation (SNP) | VAF 11/29 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747342068, CM086989, CM973641, COSV52689323, COSV52708494, COSV52979406, COSV53353999; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AC020907.6 | c.232A>G p.T78A | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.003); catalogued as COSV59534034; called by muse, varscan2
- ANP32B | c.185A>T p.K62M | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV59586903; called by muse, mutect2, varscan2
- ARFGEF1 | c.571C>A p.Q191K | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51603368, COSV99142296; called by muse, mutect2
- ATP1A1 | c.665C>G p.S222* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV55191987; called by muse, mutect2, varscan2
- BAIAP2 | c.1307A>T p.D436V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as COSV58336596; called by muse, mutect2, varscan2
- CASP8AP2 | c.368G>T p.R123I | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52747870; called by muse, mutect2, varscan2
- CD19 | c.1127C>G p.P376R | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV61188835; called by muse, mutect2, varscan2
- CHAMP1 | c.2352A>C p.L784F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63522599; called by muse, mutect2, varscan2
- CMYA5 | c.11608G>C p.D3870H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV69745755; called by muse, mutect2, varscan2
- CSF3 | c.339C>G p.S113R | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.42); PolyPhen benign (0.019); catalogued as COSV56641213, COSV99842449; called by muse, mutect2, varscan2
- DAPK1 | c.2288T>C p.M763T | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (1); PolyPhen possibly damaging (0.838); catalogued as rs748331719, COSV63788426; called by muse, mutect2, varscan2
- DMBX1 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs761306825, COSV63602176; called by muse, mutect2
- EEF1B2 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV51910720; called by muse, mutect2, varscan2
- EGFR | c.941A>G p.D314G | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV51810209; called by muse, mutect2, varscan2
- EXOC6B | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | catalogued as COSV55559202; called by muse, mutect2, varscan2
- FBXL2 | c.788+1G>T p.X263_splice | Splice Site (SNP) | VAF 41/93 reads (44%) | catalogued as COSV52139744; called by muse, mutect2, varscan2
- GP5 | c.593G>C p.R198T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV55465676; called by mutect2, varscan2
- GRXCR1 | c.771G>T p.K257N | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67672376; called by muse, mutect2, varscan2
- H1-4 | c.267C>G p.S89R | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV56801576; called by muse, mutect2, varscan2
- HIRIP3 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV54230591; called by muse, mutect2, varscan2
- HS3ST1 | c.266T>A p.F89Y | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.134); catalogued as COSV50024025; called by muse, varscan2
- IL18R1 | c.1456C>A p.P486T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52125090; called by muse, mutect2, varscan2
- ITPR1 | c.6853G>A p.V2285I (on ENST00000354582; = p.V2230I on NM_002222.7) | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs779313917, COSV56986620; called by muse, mutect2, varscan2
- LAMA1 | c.3229T>G p.C1077G | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67538991; called by muse, mutect2, varscan2
- LRAT | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV60477347; called by muse, mutect2, varscan2
- MTERF2 | c.971A>T p.E324V | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53527831; called by muse, mutect2, varscan2
- MYO5A | c.3088G>A p.E1030K | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV62561316; called by muse, mutect2, varscan2
- OR13J1 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65069801, COSV65069904; called by muse, mutect2, varscan2
- OR2Y1 | c.811A>G p.K271E | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57136752; called by muse, mutect2, varscan2
- OR7A17 | c.797A>G p.H266R | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.155); catalogued as rs1389874852, COSV59414478; called by muse, mutect2, varscan2
- OXR1 | c.819G>A p.M273I (on ENST00000442977 / NM_001198532.1; = p.M272I on NM_018002.3) | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as COSV56330817; called by muse, mutect2, varscan2
- PPIG | c.383C>G p.T128R | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53643105; called by mutect2, varscan2
- PRR5 | c.532G>T p.V178L (on ENST00000336985 / NM_181333.4; = p.V169L on NM_015366.4) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV99134336; called by muse, mutect2, varscan2
- PSPC1 | c.1198G>T p.G400* | Nonsense Mutation (SNP) | VAF 45/119 reads (38%) | catalogued as COSV58888801; called by muse, mutect2, varscan2
- RGL3 | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs953809421, COSV66509469; called by muse, mutect2, varscan2
- RIN3 | c.472C>A p.Q158K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV53650491; called by muse, mutect2, varscan2
- SERPINC1 | c.1142C>G p.S381C | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV62929670; called by muse, mutect2, varscan2
- SLC34A2 | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as COSV65941954; called by muse, mutect2, varscan2
- SLC35F1 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs746533334, COSV64504698; called by muse, mutect2, varscan2
- WDR44 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs753819771, COSV54164822; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1462A>G p.T488A | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV56273222; called by muse, mutect2, varscan2
- ZNF780B | c.1245A>T p.K415N | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99665671; called by muse, mutect2
- ARFGAP2 | c.933_941+2del p.X311_splice | Splice Site (DEL) | VAF 33/162 reads (20%) | called by mutect2, pindel, varscan2
- TARS3 | c.694_699del p.Y232_W233del | In Frame Del (DEL) | VAF 10/20 reads (50%) | called by mutect2, varscan2
- AQR | c.1668T>C p.L556= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV50037324; called by muse, mutect2, varscan2
- COG7 | c.270C>A p.V90= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV56150820; called by muse, mutect2, varscan2
- COPA | c.3219G>A p.L1073= | Silent (SNP) | VAF 27/116 reads (23%) | catalogued as COSV54104144; called by muse, mutect2, varscan2
- CSMD1 | c.9009C>A p.I3003= (on ENST00000520002; = p.I3002= on NM_033225.6) | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV59337691; called by muse, mutect2, varscan2
- DMBX1 | c.796C>T p.L266= | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as COSV63602180; called by muse, mutect2
- FAM24A | c.315C>A p.L105= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV64405973; called by muse, mutect2, varscan2
- FGFR1 | c.1758C>T p.N586= (on ENST00000447712 / NM_023110.3; = p.N584= on NM_015850.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/124 reads (14%) | catalogued as COSV58336895; called by muse, mutect2, varscan2
- HELZ2 | c.4755C>T p.H1585= (on ENST00000467148 / NM_001037335.2; = p.H1016= on NM_033405.3) | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs781050293, COSV71296176; called by muse, mutect2, varscan2
- INTS4 | c.127C>T p.L43= | Silent (SNP) | VAF 12/258 reads (5%) | catalogued as rs1410784784, COSV101417188; called by muse, mutect2
- INTS9 | c.1740C>T p.V580= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as COSV68434566; called by muse, mutect2, varscan2
- KCNN3 | c.2028G>A p.S676= (on ENST00000618040 / NM_001204087.1; = p.S661= on NM_002249.6) | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as rs1217131264, COSV55214532; called by muse, mutect2, varscan2
- KIAA0753 | c.2079C>G p.V693= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV63234763; called by muse, mutect2, varscan2
- MDM1 | c.1783C>T p.L595= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV100291716, COSV57447081; called by muse, mutect2, varscan2
- MYRF | c.624G>A p.K208= (on ENST00000278836 / NM_001127392.3; = p.K199= on NM_013279.4) | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV53890214; called by mutect2, varscan2
- PRKCB | c.1554T>C p.Y518= | Silent (SNP) | VAF 30/105 reads (29%) | catalogued as COSV57784936; called by muse, mutect2, varscan2
- PTGFRN | c.1383C>T p.S461= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs147606477, COSV67798826; called by muse, mutect2, varscan2
- PYGB | c.2226C>T p.A742= | Silent (SNP) | VAF 36/115 reads (31%) | catalogued as rs146169925, COSV99405069; called by muse, mutect2, varscan2
- SPATA2 | c.267C>T p.F89= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV56867064; called by muse, mutect2, varscan2
- TMEM245 | c.1284C>T p.V428= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as rs771275338, COSV65823250; called by muse, mutect2, varscan2
- TRIM9 | c.300C>T p.R100= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV53619049; called by muse, mutect2, varscan2
- ZNF804A | c.666G>A p.A222= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs779143111, COSV56453703; called by muse, mutect2, varscan2
- DCHS2 | n.4698G>A | RNA (SNP) | VAF 18/61 reads (30%) | catalogued as COSV61773789; called by muse, mutect2, varscan2
- ENG | c.1852+19C>A | Intron (SNP) | VAF 5/27 reads (19%) | catalogued as COSV61227789; called by muse, mutect2, varscan2
